Gene-level copy-number profile of tumor specimen TCGA-G9-6356-01A from TCGA case TCGA-G9-6356, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.3 years (22,010 days).
Specimen TCGA-G9-6356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.bab0286f-5437-4add-a929-f6d48bd21ae0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G9-6356-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba91f641-6ee9-43c2-ad0e-4722cd0ffdba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 4,968; copy number 2: 53,016; copy number 3: 1,806.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G9-6356-01A-11D-1785-01): tumor purity 0.21, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:81,875,194–82,987,179, 1 gene (within-gene range 0–2): NRG3.
- chr10:82,340,771–84,561,263, 24 genes: RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,604. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
